Gene-level copy-number profile of tumor specimen TCGA-AR-A0TV-01A from TCGA case TCGA-AR-A0TV, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 66.5 years (24,279 days).
Specimen TCGA-AR-A0TV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.5f623237-b478-4bca-8647-d633e9e63d7c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AR-A0TV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/69c8347b-c7df-4129-86d6-6f8326d79acc

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 49; copy number 1: 43; copy number 2: 12,684; copy number 3: 6,325; copy number 4: 30,525; copy number 5: 3,542; copy number 6: 3,208; copy number 7: 2,334; copy number 8: 174; copy number 9: 38; copy number 10: 188; copy number 11: 78; copy number 12: 15; copy number 13: 51; copy number 14: 62; copy number 15: 12; copy number 16: 9; copy number 17: 19; copy number 18: 38; copy number 19: 176; copy number 20: 38; copy number 21: 49; copy number 22: 17; copy number 23: 20; copy number 26: 80; copy number 29: 39; copy number 33: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AR-A0TV-01A-21D-A087-01): tumor purity 0.61, ploidy 3.77, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 49 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:149,334,024–149,773,588, 8 genes: NPM1P12, AC004941.1, AC073314.1, ZNF777, ZNF746, ZNF767P, KRBA1, ZNF467.
- chr7:150,337,483–151,144,436, 41 genes (within-gene range 0–2): AC005586.1, RARRES2, REPIN1-AS1, REPIN1, ZNF775, AC073111.2, ZNF775-AS1, AC073111.3, LINC00996, GIMAP8, AC073111.1, STRADBP1, GIMAP7, ALDH7A1P3, GIMAP4, AC069304.3, AC069304.1, GIMAP6, AC069304.2, GIMAP2, GIMAP1, GIMAP1-GIMAP5, GIMAP5, GIMAP3P, BET1P1, TMEM176B, TMEM176A, AOC1, KCNH2, NOS3, ATG9B, ABCB8, AC010973.1, ASIC3, CDK5, SLC4A2, AC010973.3, AC010973.2, FASTK, TMUB1, AGAP3.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 932 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:187,942,164–190,092,279, 50 genes, copy number 10: AC108073.3, AC108073.1, ZFP42, TRIML2, AC108073.2, RNU6-173P, TRIML1, AC138781.1, LINC02434, AC093789.1, ICE2P1, LINC01060, AC093909.3, AC093909.5, RNU7-192P, AC093909.1, AC093909.6, AC093909.2, LINC02508, AC093909.4, AC122138.1, AC107391.1, AC105924.1, HSP90AA4P, LINC01262, AF250324.1, RNU1-51P, FRG1-DT, LINC01596, FRG1, MLLT10P2, AF146191.2, TUBB7P, RNA5SP174, RNA5SP175, DUX4L9, FRG2, RARRES2P4, AGGF1P1, CLUHP4, DBET, U85056.1, DUX4L8, DUX4L7, DUX4L6, DUX4L5, DUX4L4, DUX4L1, DUX4L3, DUX4L2.
- chr5:53,413,504–53,881,051, 6 genes, copy number 10: AC108114.1, FST, NDUFS4, LINC02105, ASS1P9, AC025175.1.
- chr5:53,897,464–54,048,308, 4 genes, copy number 10: AC025175.2, RNU6-272P, MIR581, RN7SL801P.
- chr5:88,883,328–89,990,883, 4 genes, copy number 10 (within-gene range 1–10): MEF2C-AS1, AC074131.1, LINC02161, AC113167.1.
- chr5:165,220,577–166,926,370, 9 genes, copy number 9–26: LINC01938, AC008415.1, RN7SKP60, AC008562.1, AC008489.1, RPL7P20, AC114321.1, AC026403.1, LINC01947.
- chr5:172,834,251–174,995,513, 52 genes, copy number 9–14: ERGIC1, AC008429.1, AC008429.3, RPL26L1, AC008429.2, ATP6V0E1, AC008429.4, SNORA74B, Y_RNA, CREBRF, CDC42P5, AC008378.1, BNIP1, RPL7AP33, NKX2-5, Y_RNA, RNA5SP200, STC2, MIR8056, RNU6-500P, AC016573.1, AC008632.1, AC008663.1, AC008663.3, AC008663.2, BOD1, LINC01863, LINC01942, LINC01484, AC008674.1, LINC01485, CPEB4, C5orf47, RPL12P22, NSG2, AC113423.1, AC113423.2, AC011333.1, AC025752.1, LINC01411, GAPDHP71, SUMO2P6, AC108112.1, HIGD1AP3, MSX2, AC113346.2, MIR4634, AC113346.1, LINC01951, NIFKP2, AC008413.1, AC008413.2.
- chr8:65,644,734–66,518,524, 18 genes, copy number 11: MTFR1, AC055822.1, PDE7A, AC100812.1, DNAJC5B, AC084082.1, TRIM55, CRH, LINC00967, AC009879.4, RRS1-AS1, RRS1, AC009879.2, AC009879.3, ADHFE1, AC009879.1, VXN, RNU6-1324P.
- chr8:67,952,046–72,251,565, 60 genes, copy number 11 (within-gene range 4–11): PREX2, AC011853.2, AC011853.1, Y_RNA, RPL31P40, C8orf34-AS1, C8orf34, RPS15AP25, RNA5SP269, AC083967.1, LINC01592, RNU7-102P, AF201337.1, AC021785.1, LINC01603, AC022790.1, SULF1, SLCO5A1, RN7SKP29, AC091047.1, AC079089.3, AC079089.1, Metazoa_SRP, AC079089.2, RN7SL675P, RNA5SP270, AC090574.1, SDCBPP2, SUMO2P20, PRDM14, RNU1-101P, H2AZP2, NCOA2, BTF3P12, RNY3P14, AC022730.2, AC022730.3, AC022730.4, RN7SL203P, AC022730.1, AC120194.1, TRAM1, LACTB2-AS1, LACTB2, RN7SL19P, XKR9, AC015687.1, Y_RNA, AC022858.1, EYA1, TRAPPC2P2, AC009446.1, AC104012.1, U8, MSC-AS1, MSC, RPS20P20, TRPA1, AC078906.1, AC022905.1.
- chr8:76,162,119–78,605,267, 19 genes, copy number 17 (within-gene range 2–17): AC011029.1, RNU2-54P, AC067773.1, LINC01109, LINC01111, ZFHX4-AS1, AC013509.1, MRPL9P1, ZFHX4, AC011716.1, AC023200.1, MIR3149, PEX2, HIGD1AP18, AC062004.1, AC084706.1, PKIA-AS1, RNU6-1220P, PKIA.
- chr8:80,484,561–81,759,515, 42 genes, copy number 14–23: AC009812.1, Y_RNA, ZBTB10, AC009812.3, AC009812.4, RPSAP47, RNU7-174P, AC009812.2, RNU2-71P, SLC25A51P3, RN7SL107P, ZNF704, CKS1BP7, RNU11-6P, RN7SL308P, HMGB1P41, AC012533.1, PAG1, AC022778.1, AC079209.2, AC079209.1, AC009902.1, UBE2HP1, AC009902.3, AC009902.2, FABP5, AC018616.1, PMP2, FABP9, FABP4, AC023644.1, FTH1P11, FABP12, IMPA1P1, NIPA2P4, RPS26P34, SLC10A5P1, IMPA1, SLC10A5, AC132219.2, ZFAND1, CHMP4C.
- chr8:83,293,925–86,743,675, 57 genes, copy number 14–22 (within-gene range 7–22): AC090132.2, LINC01419, AC015522.1, TPM3P3, AC012400.1, RALYL, RNU6-1040P, PSMC2P2, AC009901.1, AC009901.2, ACTBP6, JCHAINP1, AC091175.1, LRRCC1, AC011773.4, E2F5, AC011773.1, RBIS, CA13, AC011773.3, AC011773.2, CA1, CA3, CA3-AS1, CA2, AC084734.1, AC093331.1, REXO1L8P, REXO1L3P, REXO1L1P, REXO1L12P, REXO1L11P, REXO1L10P, REXO1L9P, REXO1L2P, AC232323.1, REXO1L4P, REXO1L5P, REXO1L6P, AC100801.1, LINC02849, AC100801.2, ATP6V0D2, AC023194.1, AC023194.2, PSKH2, AC023194.3, AC084128.1, SLC7A13, AC103760.1, WWP1, RMDN1, NTAN1P2, SLC2A3P4, CPNE3, CNGB3, MIOXP1.
- chr8:86,707,547–86,765,023, 1 gene, copy number 18 (within-gene range 7–18): AC090572.3.
- chr8:92,668,660–119,712,145, 390 genes, copy number 12–33 (broad region; genes not listed).
- chr8:121,668,934–121,697,600, 1 gene, copy number 21 (within-gene range 7–21): LINC02855.
- chr8:124,550,784–126,558,478, 33 genes, copy number 18 (within-gene range 7–18): MTSS1, AC100858.2, MIR4662B, MIR4662A, LINC00964, MRS2P1, AC100858.1, AC100858.3, ZNF572, AC009908.1, SQLE, WASHC5, WASHC5-AS1, NSMCE2, RN7SL329P, AC084083.1, TRIB1, AC091114.1, AC016074.2, AC016074.1, LINC00861, RNU6-442P, SOD1P3, AC024681.2, KNOP1P5, AC024681.1, RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2.
- chr8:126,582,631–126,846,981, 3 genes, copy number 18 (within-gene range 7–18): AC083923.1, RNU11-4P, AC024382.1.
- chr11:68,612,899–69,926,813, 36 genes, copy number 10: AP003096.1, GAL, TESMIN, CPT1A, LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2.
- chr11:76,435,559–77,126,155, 19 genes, copy number 10 (within-gene range 4–10): AP002360.1, EMSY, AP001189.2, LINC02757, AP001189.5, AP001189.3, AP001189.1, LRRC32, AP001189.4, GUCY2EP, AP003119.1, TSKU, AP003119.2, AP003119.3, ACER3, AP002498.1, B3GNT6, CAPN5, OMP.
- chr11:77,313,606–82,718,299, 62 genes, copy number 9–20 (within-gene range 2–20) (broad region; genes not listed).
- chr14:33,597,057–36,320,637, 64 genes, copy number 10 (broad region; genes not listed).
- chr14:36,371,165–36,405,274, 2 genes, copy number 10: DPPA3P2, RNU7-93P.

Autosomal genes at a single copy (total copy number 1): 43. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
